Somatic mutation profile of tumor specimen TCGA-5A-A8ZF-01A (aliquot TCGA-5A-A8ZF-01A-12D-A46P-09) from TCGA case TCGA-5A-A8ZF, project TCGA-CHOL (Cholangiocarcinoma).
Specimen TCGA-5A-A8ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f94982f4-67a6-422f-8d6a-66c5e3a026db.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5A-A8ZF-10A (Blood Derived Normal), aliquot TCGA-5A-A8ZF-10A-01D-A46P-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1d2fd250-abc7-4674-9560-77318c29a087

The open-access MAF lists 116 somatic variants for this specimen: 83 protein-altering or splice-affecting, 30 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 30, Nonsense Mutation 6, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, Splice Region 2, Intron 2, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HUWE1 | c.12188G>A p.R4063Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs1569399945, CM165683, COSV53350390, COSV99473238; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 9/51 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/117 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ADAM2 | c.1223T>G p.L408R | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs759673514, COSV55861720, COSV99696709; called by muse, mutect2, varscan2
- ANXA10 | c.951T>A p.C317* | Nonsense Mutation (SNP) | VAF 27/113 reads (24%) | catalogued as COSV63739233; called by muse, mutect2, varscan2
- ARID1A | c.5578G>T p.E1860* | Nonsense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV61386185; called by muse, mutect2, varscan2
- C11orf87 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs769295324, COSV59358927; called by muse, mutect2, varscan2
- CACNG5 | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs765113947, COSV50054665; called by muse, mutect2, varscan2
- CLDN17 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs781665299, COSV54522109, COSV99729551; called by muse, mutect2, varscan2
- CNNM4 | c.1210G>A p.G404S | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65660203; called by muse, mutect2, varscan2
- DIAPH3 | c.2287G>A p.D763N (on ENST00000400324 / NM_001042517.2; = p.D500N on NM_030932.3) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1327735988; called by muse, mutect2, varscan2
- EPX | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs764554374, COSV56598141; called by muse, varscan2
- ERICH3 | c.3536G>C p.G1179A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs774952324, COSV58606789; called by mutect2, varscan2
- GALNT8 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs151313517; called by muse, mutect2, varscan2
- GUCY2C | c.2506A>G p.I836V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs1278157826; called by muse, mutect2, varscan2
- HYAL1 | c.649T>G p.Y217D | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs916207090; called by muse, mutect2, varscan2
- KSR2 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs185272487, COSV56667008; called by muse, mutect2, varscan2
- LAMA1 | c.2737G>A p.V913M | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.19); catalogued as rs762641681, COSV101056591, COSV67544778; called by muse, mutect2
- LCTL | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780938630, COSV58423243; called by muse, mutect2, varscan2
- LHX6 | c.64G>A p.A22T (on ENST00000373755 / NM_001242334.2; = p.A51T on NM_014368.5) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as rs1362909237; called by muse, mutect2, varscan2
- LTBP2 | c.4693C>T p.R1565C | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs750269632, COSV56213070; called by muse, mutect2, varscan2
- MYH6 | c.5335G>A p.A1779T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs777220078, COSV59306546; called by muse, mutect2, varscan2
- NLRP3 | c.1896G>T p.L632F | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs180177446, CM043753; ClinVar: not provided; called by muse, mutect2
- NUP133 | c.3301T>G p.F1101V | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99772462; called by muse, mutect2, varscan2
- NUP210L | c.3230G>A p.R1077Q | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs781242352, COSV55148482; called by muse, mutect2, varscan2
- OTUD7A | c.1485T>G p.N495K (on ENST00000307050 / NM_001382637.1; = p.N488K on NM_130901.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as rs148643263; called by muse, mutect2, varscan2
- PCDHGB5 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.09); catalogued as rs1346018954; called by muse, mutect2, varscan2
- PLCD3 | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV59560197; called by muse, mutect2, varscan2
- RPGRIP1L | c.2230C>T p.R744* | Nonsense Mutation (SNP) | VAF 20/90 reads (22%) | catalogued as rs267604575, COSV50910819, COSV50911131; called by muse, mutect2, varscan2
- SGSM2 | c.1234C>T p.R412W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs199896619, COSV52159760; called by muse, mutect2, varscan2
- SH3BGRL | c.229G>A p.G77R | Missense Mutation (SNP) | VAF 18/134 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767134075, COSV64622024; called by muse, mutect2, varscan2
- SHPRH | c.4356del p.C1453Vfs*7 (on ENST00000275233 / NM_001042683.3; = p.C1457Vfs*7 on NM_173082.3) | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as COSV99261804; called by mutect2, pindel, varscan2
- SMAP2 | c.946C>T p.P316S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1437341990; called by muse, mutect2
- ZMYM3 | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.19); catalogued as rs370506452; called by muse, mutect2, varscan2
- ZNF229 | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.392); catalogued as COSV99350338; called by muse, mutect2, varscan2
- AGTR2 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- AMOTL2 | c.2140C>T p.P714S (on ENST00000422605; = p.P715S on NM_016201.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ANKLE1 | c.955C>T p.Q319* (on ENST00000394458; = p.Q265* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- C1GALT1C1L | c.106C>T p.Q36* | Nonsense Mutation (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- CEP76 | c.805-2A>C p.X269_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- CFHR5 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- CGNL1 | c.569C>G p.T190S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CLEC12B | c.680+5G>C | Splice Region (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- CNOT10 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- CTSC | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- DOCK3 | c.3377A>C p.Q1126P | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ELL2 | c.982G>C p.D328H | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAM120C | c.2470T>G p.F824V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- IRX1 | c.302A>C p.N101T | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.101); called by muse, mutect2
- IZUMO1R | c.724del p.L242Ffs*? (on ENST00000440961; = p.L249Ffs*? on NM_001199206.3) | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- LCA5L | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRSAM1 | c.1849G>A p.G617S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- LYST | c.3231A>C p.E1077D | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH6 | c.1277_1278del p.C426Lfs*8 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- MST1 | c.1849G>A p.E617K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC5B | c.5811dup p.V1938Sfs*186 | Frame Shift Ins (INS) | VAF 16/107 reads (15%) | called by mutect2, pindel, varscan2
- NAV1 | c.3620dup p.K1208Efs*9 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- NEFM | c.1515A>C p.E505D | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NEXMIF | c.4423G>T p.D1475Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NLGN4X | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NME8 | c.322A>T p.K108* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- OR11L1 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- PNPLA6 | c.2809C>T p.P937S (on ENST00000414982 / NM_001166111.2; = p.P889S on NM_006702.5) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- PRKD1 | c.1977G>T p.M659I | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RASAL2 | c.2234G>A p.S745N | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- RELCH | c.1128G>C p.L376F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- RYR3 | c.7669C>G p.L2557V (on ENST00000389232; = p.L2558V on NM_001036.6) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SCN11A | c.1909T>G p.F637V | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCN1A | c.1171-2A>T p.X391_splice | Splice Site (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- SLC4A7 | c.485T>G p.L162R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMAD4 | c.1196_1213del p.V399_H405delinsD | In Frame Del (DEL) | VAF 9/63 reads (14%) | called by mutect2, pindel, varscan2
- SMC1B | c.2532A>T p.K844N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- SPAG16 | c.1379G>C p.S460T | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- STAC3 | c.725A>T p.K242M | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SYNM | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- TMC2 | c.2178C>T p.F726= | Splice Region (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- TRIM51 | c.1009A>G p.T337A | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TRRAP | c.9092T>A p.M3031K (on ENST00000359863 / NM_001244580.1; = p.M3002K on NM_003496.3) | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UBE2Q2 | c.537T>G p.N179K | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- ZFHX4 | c.5786A>G p.Q1929R | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZNF407 | c.2228C>T p.S743L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ZNF626 | c.1304A>C p.N435T | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.24); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF667 | c.466A>G p.S156G | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVR2A | c.105T>G p.A35= | Silent (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- ADD2 | c.39G>A p.P13= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs782510605, COSV100034359; called by muse, mutect2, varscan2
- BCAR3 | c.624C>G p.L208= | Silent (SNP) | VAF 9/26 reads (35%) | called by muse, mutect2, varscan2
- EFS | c.237G>A p.A79= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs141340036; called by muse, mutect2, varscan2
- GALNT3 | c.1833G>A p.E611= | Silent (SNP) | VAF 11/66 reads (17%) | called by muse, mutect2, varscan2
- GPR161 | c.516C>T p.D172= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs200671514; called by muse, mutect2, varscan2
- H3C1 | c.410G>A p.*137= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs957461655; called by muse, mutect2, varscan2
- HIC2 | c.132C>T p.F44= | Silent (SNP) | VAF 9/31 reads (29%) | called by muse, mutect2, varscan2
- IRX2 | c.372C>T p.D124= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as rs1014895683, COSV100121589, COSV57409988; called by muse, mutect2, varscan2
- KCNN2 | c.405C>T p.S135= (on ENST00000264773; = p.S347= on NM_021614.4) | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV53283145; called by muse, mutect2, varscan2
- MAOB | c.18C>T p.D6= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- OR10G7 | c.27G>A p.A9= | Silent (SNP) | VAF 20/104 reads (19%) | catalogued as rs757564463; called by muse, mutect2
- OR4A15 | c.822T>G p.T274= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV59035832; called by muse, mutect2
- OR8B3 | c.519C>T p.I173= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as rs752996656, COSV63541570; called by muse, mutect2, varscan2
- OSMR | c.543G>A p.L181= | Silent (SNP) | VAF 28/120 reads (23%) | called by muse, mutect2, varscan2
- PDE4DIP | c.4395G>A p.L1465= | Silent (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- POU4F3 | c.849G>A p.A283= | Silent (SNP) | VAF 6/29 reads (21%) | catalogued as rs138424542, COSV57942997; called by muse, mutect2
- PPM1N | c.879C>T p.L293= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- PRRC2B | c.2983C>T p.L995= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs1387063497, COSV61939100; called by muse, mutect2, varscan2
- RNF10 | c.879G>T p.T293= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as COSV58043245; called by muse, mutect2, varscan2
- SLC34A3 | c.567C>T p.F189= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs780404941; called by mutect2, varscan2
- SLFN12 | c.171A>G p.G57= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV59225709; called by muse, mutect2
- SPTB | c.6513C>A p.A2171= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- STK36 | c.3472C>T p.L1158= | Silent (SNP) | VAF 7/18 reads (39%) | called by muse, mutect2, varscan2
- TMEM97 | c.114C>T p.L38= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, varscan2
- TRPV4 | c.2286C>T p.V762= | Silent (SNP) | VAF 9/55 reads (16%) | called by muse, mutect2, varscan2
- ZNF37A | c.1665C>T p.N555= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs752327412, COSV61074006; called by muse, mutect2, varscan2
- ZNF611 | c.885C>A p.T295= | Silent (SNP) | VAF 14/105 reads (13%) | called by muse, mutect2, varscan2
- ZNF688 | c.813C>T p.I271= | Silent (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- ZNF91 | c.489C>T p.F163= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100323437; called by muse, mutect2, varscan2
- HUWE1 | c.8206+121A>G | Intron (SNP) | VAF 9/58 reads (16%) | catalogued as COSV99470602; called by muse, mutect2, varscan2
- SH3KBP1 | c.521-3608G>A | Intron (SNP) | VAF 11/61 reads (18%) | catalogued as rs1186213233; called by muse, mutect2, varscan2
- ZNFX1 | chr20:49280698 G>A | 5'Flank (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
